Somatic mutation profile of tumor specimen TCGA-3A-A9J0-01A (aliquot TCGA-3A-A9J0-01A-11D-A40W-08) from TCGA case TCGA-3A-A9J0, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 75.2 years (27,453 days).
Specimen TCGA-3A-A9J0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b90a815-35d4-44ed-bb25-7ddb100bf3df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3A-A9J0-10A (Blood Derived Normal), aliquot TCGA-3A-A9J0-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aaabf288-4072-45bc-8bfb-3377cd6d5d75

The open-access MAF lists 89 somatic variants for this specimen: 67 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 57, Silent 22, Nonsense Mutation 5, Frame Shift Del 2, Frame Shift Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 90/277 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 77/182 reads (42%) | hotspot (GDC flag); catalogued as rs1131691042, CS137624, COSV52670017, COSV52686439, COSV52695669; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASDH | c.500_504del p.I167Kfs*5 | Frame Shift Del (DEL) | VAF 47/299 reads (16%) | catalogued as rs1444451781; called by mutect2, pindel, varscan2
- ABCB6 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.773); catalogued as rs1256856094, COSV99522379; called by muse, mutect2
- ADAMTS19 | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 317/567 reads (56%) | catalogued as COSV99183858; called by muse, mutect2, varscan2
- ALS2CL | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV100015375; called by muse, mutect2, varscan2
- APLP2 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 99/540 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.508); catalogued as COSV99600159; called by muse, mutect2, varscan2
- ARHGAP21 | c.154A>C p.T52P | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as COSV100903734; called by muse, mutect2
- ASPM | c.6095G>A p.R2032H | Missense Mutation (SNP) | VAF 89/436 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs149033840, COSV54128644; called by muse, mutect2, varscan2
- ATXN2L | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 55/292 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57365138; called by muse, mutect2, varscan2
- CACNA1H | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 48/322 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs772154386, COSV61988665; called by muse, mutect2, varscan2
- CKAP2L | c.874T>C p.S292P | Missense Mutation (SNP) | VAF 158/551 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100198830; called by muse, mutect2, varscan2
- COL6A2 | c.2093C>T p.A698V | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1085307668, COSV100154467; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPXM2 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 20/295 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.227); catalogued as rs199927775, COSV99582589; called by muse, mutect2
- CSMD2 | c.5143G>A p.A1715T | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs529128430, COSV53903887; called by muse, mutect2, varscan2
- DCLK3 | c.503A>G p.K168R | Missense Mutation (SNP) | VAF 188/595 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV101374174, COSV69363388; called by muse, mutect2, varscan2
- DHX38 | c.817A>T p.K273* | Nonsense Mutation (SNP) | VAF 58/172 reads (34%) | catalogued as COSV99194666; called by muse, mutect2, varscan2
- DISP1 | c.1123G>A p.V375I | Missense Mutation (SNP) | VAF 121/375 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.314); catalogued as rs755916120, COSV99452406; called by muse, mutect2, varscan2
- DSCAM | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs779784450, COSV101261727; called by muse, mutect2, varscan2
- EPHA7 | c.2630G>A p.R877H | Missense Mutation (SNP) | VAF 118/367 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs755970343, COSV65178391, COSV65183780, COSV65193538; called by muse, mutect2, varscan2
- FAR1 | c.1338G>T p.L446F | Missense Mutation (SNP) | VAF 60/365 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV100701678; called by muse, mutect2, varscan2
- FASTKD5 | c.779G>A p.R260K | Missense Mutation (SNP) | VAF 42/321 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as COSV99418685; called by muse, mutect2, varscan2
- FGD4 | c.752A>G p.N251S | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as COSV99847725; called by muse, mutect2, varscan2
- GCC2 | c.2978A>G p.E993G | Missense Mutation (SNP) | VAF 116/433 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV100565684; called by muse, mutect2, varscan2
- GLI3 | c.1540G>A p.V514M | Missense Mutation (SNP) | VAF 135/438 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs148502119; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR39 | c.897C>G p.N299K | Missense Mutation (SNP) | VAF 88/369 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.947); catalogued as COSV100258795; called by muse, mutect2, varscan2
- HIVEP3 | c.6848G>A p.G2283E | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99914260; called by muse, mutect2, varscan2
- HSD17B13 | c.49T>C p.S17P | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.526); catalogued as rs1179391078, COSV100143367; called by muse, mutect2, varscan2
- IFNGR1 | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 94/280 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV100880545; called by muse, mutect2, varscan2
- ITPR1 | c.2812C>T p.R938W (on ENST00000354582; = p.R923W on NM_002222.7) | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs777634985, COSV100231990; called by muse, mutect2, varscan2
- LAMA4 | c.1354G>A p.E452K (on ENST00000230538 / NM_001105206.3; = p.E445K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 174/426 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.033); catalogued as rs1554343251, COSV57895901; called by muse, mutect2, varscan2
- MAP1B | c.5689C>T p.R1897W | Missense Mutation (SNP) | VAF 195/325 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs757286026, COSV99703033; called by muse, mutect2, varscan2
- MAP1B | c.5902G>A p.E1968K | Missense Mutation (SNP) | VAF 84/472 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs999621263, COSV57095515, COSV99702129; called by muse, mutect2, varscan2
- MISP | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs748948057, COSV99297190; called by muse, mutect2, varscan2
- MYH15 | c.2428C>T p.R810* | Nonsense Mutation (SNP) | VAF 34/264 reads (13%) | catalogued as rs201762535; called by muse, mutect2, varscan2
- MYO5C | c.2524C>T p.R842* | Nonsense Mutation (SNP) | VAF 364/1477 reads (25%) | catalogued as rs999922874, COSV55904334; called by muse, mutect2, varscan2
- NUF2 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as rs775293541, COSV54842355; called by muse, mutect2, varscan2
- OR2M4 | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 113/824 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100141580, COSV60707400; called by muse, mutect2, varscan2
- PASK | c.2690G>A p.S897N | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.052); catalogued as COSV99300430; called by muse, mutect2, varscan2
- PCDH11Y | c.2812G>C p.D938H (on ENST00000400457 / NM_032973.2; = p.D927H on NM_032971.3) | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99293059; called by muse, mutect2, varscan2
- PCDH17 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100931719, COSV100932160; called by muse, mutect2, varscan2
- PCDHB7 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 91/464 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as rs782787249, COSV50769598; called by muse, mutect2, varscan2
- PHLPP1 | c.2363T>G p.L788R | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99409509; called by muse, mutect2, varscan2
- PKNOX2 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 99/545 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs758257491, COSV100022085; called by muse, mutect2, varscan2
- PPP1R16B | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs868199379, COSV100240195; called by muse, mutect2, varscan2
- PRSS35 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs541411659, COSV63800286; called by muse, mutect2, varscan2
- RELCH | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.753); catalogued as COSV99902944; called by muse, mutect2, varscan2
- RGMA | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs201119116, COSV61232849; called by muse, mutect2, varscan2
- S100A3 | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 94/602 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100573168; called by muse, mutect2
- SSX2IP | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.734); catalogued as rs1171194235, COSV60552791, COSV60553122; called by muse, mutect2
- STAC | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99830021, COSV99830933; called by muse, mutect2, varscan2
- TBC1D10A | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 51/342 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99305034; called by muse, mutect2, varscan2
- TBCCD1 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 216/759 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.401); catalogued as COSV100112177; called by muse, mutect2, varscan2
- TCF4 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.905); catalogued as COSV61894052; called by muse, mutect2, varscan2
- TEK | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 60/262 reads (23%) | catalogued as COSV101193633; called by muse, mutect2, varscan2
- TNXB | c.1930G>A p.G644S | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764261572, COSV64476493; called by muse, mutect2, varscan2
- TRPM6 | c.4592G>A p.R1531H | Missense Mutation (SNP) | VAF 58/288 reads (20%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs199963114, COSV100667090; called by muse, mutect2, varscan2
- ULK1 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 98/172 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs745463834, COSV100417357; called by muse, mutect2, varscan2
- UVRAG | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 60/304 reads (20%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1258646909, COSV100638700; called by muse, mutect2, varscan2
- WDR89 | c.52T>A p.L18I | Missense Mutation (SNP) | VAF 149/583 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99962614; called by muse, mutect2, varscan2
- WNT3A | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99470272; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2620T>G p.F874V | Missense Mutation (SNP) | VAF 77/557 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100048628; called by muse, mutect2, varscan2
- ZNF605 | c.1861G>C p.E621Q | Missense Mutation (SNP) | VAF 147/365 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV100053584; called by muse, mutect2, varscan2
- ANKRD50 | c.621dup p.T208Yfs*16 | Frame Shift Ins (INS) | VAF 215/753 reads (29%) | called by mutect2, pindel, varscan2
- ARSK | c.785dup p.N262Kfs*12 | Frame Shift Ins (INS) | VAF 113/375 reads (30%) | called by mutect2, pindel, varscan2
- ITK | c.1231A>G p.M411V | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- MYH7B | c.3985_3986del p.Q1329Dfs*60 | Frame Shift Del (DEL) | VAF 69/449 reads (15%) | called by mutect2, pindel, varscan2
- ADCY1 | c.1368G>A p.P456= | Silent (SNP) | VAF 148/461 reads (32%) | catalogued as rs149589767; called by muse, mutect2, varscan2
- CARD19 | c.42G>A p.T14= | Silent (SNP) | VAF 52/125 reads (42%) | catalogued as rs770515947, COSV64935899; called by muse, mutect2, varscan2
- CDC42BPA | c.3168C>T p.N1056= (on ENST00000334218 / NM_001366019.2; = p.N1043= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 77/478 reads (16%) | catalogued as COSV100507109; called by muse, mutect2, varscan2
- EP400 | c.108G>A p.P36= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs767249896, COSV57772242; called by muse, mutect2, varscan2
- FERMT2 | c.201G>A p.K67= | Silent (SNP) | VAF 123/931 reads (13%) | catalogued as rs567979465, COSV100448736, COSV100449208; called by muse, mutect2, varscan2
- IL2RA | c.426C>T p.F142= | Silent (SNP) | VAF 91/420 reads (22%) | catalogued as rs763915787, COSV56920007, COSV56920413, COSV99906391; called by muse, mutect2, varscan2
- KIF1A | c.2505C>T p.T835= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as rs370648599; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KL | c.2625C>T p.I875= | Silent (SNP) | VAF 221/596 reads (37%) | catalogued as rs756905480, COSV66308927; called by muse, mutect2, varscan2
- LPA | c.4266G>A p.R1422= | Silent (SNP) | VAF 318/937 reads (34%) | catalogued as COSV60302556; called by muse, mutect2, varscan2
- LZTS1 | c.1650C>T p.Y550= | Silent (SNP) | VAF 111/484 reads (23%) | catalogued as rs778252648, COSV56116337; called by muse, mutect2, varscan2
- MUC21 | c.1284C>T p.T428= | Silent (SNP) | VAF 95/691 reads (14%) | catalogued as COSV100888949; called by muse, mutect2, varscan2
- NLRP7 | c.1242G>A p.T414= | Silent (SNP) | VAF 40/133 reads (30%) | catalogued as rs751935141, COSV60173764; called by muse, mutect2, varscan2
- OR7G1 | c.711G>A p.A237= | Silent (SNP) | VAF 61/243 reads (25%) | catalogued as rs138779373, COSV99528842; called by muse, mutect2, varscan2
- PCDH8 | c.2253C>T p.I751= | Silent (SNP) | VAF 35/310 reads (11%) | catalogued as rs778627492, COSV100132119; called by muse, mutect2, varscan2
- PPM1F | c.1023C>T p.A341= | Silent (SNP) | VAF 52/219 reads (24%) | catalogued as rs767252037, COSV54284594; called by muse, mutect2, varscan2
- RFC4 | c.165G>A p.Q55= | Silent (SNP) | VAF 112/655 reads (17%) | catalogued as COSV99961413; called by muse, mutect2, varscan2
- RNF17 | c.4356C>T p.S1452= | Silent (SNP) | VAF 161/550 reads (29%) | catalogued as rs200797570, COSV99694648; called by muse, mutect2, varscan2
- SEPTIN1 | c.345C>T p.A115= (on ENST00000321367; = p.A68= on NM_052838.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/1062 reads (3%) | catalogued as COSV100363186, COSV58443390; called by muse, mutect2
- SLAIN1 | c.669G>A p.A223= (on ENST00000466548; = p.A81= on NM_001040153.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 123/1048 reads (12%) | catalogued as rs775808483, COSV99935565; called by muse, mutect2, varscan2
- SPATA2L | c.765G>A p.A255= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as rs778118142, COSV99232610; called by muse, varscan2
- UBQLN4 | c.1290C>T p.F430= | Silent (SNP) | VAF 51/392 reads (13%) | catalogued as rs192302628, COSV100849371; called by muse, mutect2, varscan2
- USP31 | c.681T>C p.H227= | Silent (SNP) | VAF 72/393 reads (18%) | catalogued as COSV99566063; called by muse, mutect2, varscan2
